Somatic mutation profile of tumor specimen MP2PRT-PASUBB-TMP1-A (aliquot MP2PRT-PASUBB-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASUBB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,858 days).
Specimen MP2PRT-PASUBB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9be1dd69-374d-483b-a783-a7cb6afad658.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASUBB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASUBB-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d925794f-618a-4a4b-84d5-52d824930a2e

The open-access MAF lists 36 somatic variants for this specimen: 29 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 6, Nonsense Mutation 2, Frame Shift Ins 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 346/1016 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2663G>A p.R888H | Missense Mutation (SNP) | VAF 433/1040 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.218); catalogued as rs978993413; called by muse, mutect2, varscan2
- ADGRB3 | c.3875C>A p.A1292D | Missense Mutation (SNP) | VAF 25/534 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV53239342; called by muse, mutect2
- ARMC3 | c.1561G>A p.G521R | Missense Mutation (SNP) | VAF 116/417 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99957937; called by muse, mutect2, varscan2
- CARMIL2 | c.3079C>T p.R1027C | Missense Mutation (SNP) | VAF 261/602 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); catalogued as rs1446107172; called by muse, mutect2, varscan2
- CDH26 | c.1015G>A p.V339I | Missense Mutation (SNP) | VAF 65/395 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.444); catalogued as rs375794584; called by muse, mutect2, varscan2
- DNAH10 | c.5127G>A p.M1709I (on ENST00000409039; = p.M1648I on NM_207437.3) | Missense Mutation (SNP) | VAF 117/1112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68990249, COSV68996365; called by muse, mutect2, varscan2
- HAS1 | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 186/496 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs749715354, COSV55786297, COSV55787865; called by muse, mutect2, varscan2
- PRSS56 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 269/682 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1028701908, COSV51329899; called by muse, mutect2, varscan2
- TOPBP1 | c.3664C>G p.P1222A | Missense Mutation (SNP) | VAF 277/794 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV53438230; called by muse, mutect2, varscan2
- ZNF462 | c.2798C>T p.T933M | Missense Mutation (SNP) | VAF 354/798 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763260640; called by muse, mutect2, varscan2
- ADHFE1 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 154/521 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.196); called by muse, mutect2
- AMBN | c.1311G>A p.M437I | Missense Mutation (SNP) | VAF 22/702 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- AP4S1 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 94/540 reads (17%) | called by muse, mutect2, varscan2
- ARHGAP5 | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 100/669 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- COL21A1 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 16/441 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2
- COL3A1 | c.2638C>T p.L880F | Missense Mutation (SNP) | VAF 22/898 reads (2%) | SIFT tolerated (0.13); PolyPhen benign (0.235); called by muse, mutect2
- ERN2 | c.1472A>T p.Q491L | Missense Mutation (SNP) | VAF 364/854 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IGHV1-58 | c.349_350insTCCGCGG p.A117Vfs*? | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | called by mutect2, pindel
- ITPKA | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 225/575 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- MALRD1 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 16/572 reads (3%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.85); called by muse, mutect2
- NOM1 | c.1116G>C p.L372F | Missense Mutation (SNP) | VAF 19/479 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2
- PCCA | c.1882C>T p.Q628* | Nonsense Mutation (SNP) | VAF 20/704 reads (3%) | called by muse, mutect2
- PRR23C | c.263T>G p.L88R | Missense Mutation (SNP) | VAF 394/903 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- RASA2 | c.1607G>C p.R536T | Missense Mutation (SNP) | VAF 103/570 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SPHKAP | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 299/814 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UHRF1 | c.433del p.D145Tfs*15 (on ENST00000612630 / NM_001290050.1; = p.D158Tfs*15 on NM_013282.4) | Frame Shift Del (DEL) | VAF 183/561 reads (33%) | called by pindel*, varscan2
- WDR75 | c.2460G>C p.R820S | Missense Mutation (SNP) | VAF 124/330 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- ZNF84 | c.2080C>G p.Q694E | Missense Mutation (SNP) | VAF 32/978 reads (3%) | SIFT tolerated (0.72); PolyPhen benign (0.006); called by muse, mutect2
- CELF4 | c.1302C>T p.D434= | Silent (SNP) | VAF 300/754 reads (40%) | catalogued as rs201310208; called by muse, mutect2, varscan2
- EDRF1 | c.3336G>A p.V1112= (on ENST00000356792 / NM_001202438.2; = p.V1078= on NM_015608.2) | Silent (SNP) | VAF 113/679 reads (17%) | catalogued as rs188462280, COSV61766789; called by muse, mutect2, varscan2
- EYS | c.2757G>T p.G919= | Silent (SNP) | VAF 20/558 reads (4%) | called by muse, mutect2
- PLAC8L1 | c.70C>T p.L24= | Silent (SNP) | VAF 10/310 reads (3%) | called by muse, mutect2
- TAF15 | c.1778G>A p.*593= (on ENST00000605844 / NM_139215.3; = p.*590= on NM_003487.4) | Silent (SNP) | VAF 44/1073 reads (4%) | called by muse, mutect2
- TOLLIP | c.669G>A p.V223= | Silent (SNP) | VAF 465/1097 reads (42%) | called by muse, mutect2, varscan2
- WWOX | c.1056+324219C>G | Intron (SNP) | VAF 235/763 reads (31%) | catalogued as rs190188497; called by muse, mutect2, varscan2
